Gene-level copy-number profile of tumor specimen TCGA-AC-A3OD-01A from TCGA case TCGA-AC-A3OD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.0 years (25,186 days).
Specimen TCGA-AC-A3OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1a425572-ceb5-4f65-89c4-8fb8bc4c648e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A3OD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/128fece3-4dad-45b4-99e0-5738fd12ac27

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,384; copy number 2: 41,147; copy number 3: 3,959; copy number 4: 2,125; copy number 5: 991; copy number 6: 142; copy number 8: 68.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A3OD-01A-11D-A21P-01): tumor purity 0.42, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,201 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:210,676,823–211,134,165, 1 gene, copy number 5 (within-gene range 4–5): KCNH1.
- chr1:210,858,125–248,919,946, 835 genes, copy number 5 (broad region; genes not listed).
- chr11:68,903,863–79,441,030, 328 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:81,552,226–83,423,516, 37 genes, copy number 5: MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.

Autosomal genes at a single copy (total copy number 1): 9,951. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
